Surgical pathology report (de-identified scan), TCGA case TCGA-YZ-A985, project TCGA-UVM (Uveal Melanoma), tissue source site The Ohio State University, specimen TCGA-YZ-A985-01A (Primary Tumor).

[page 1 of 3]
Facility

Name

Result Information

Status
Edited

Provider Status
Reviewed

MD on

MD on

Observation Date and Time

Entry Date

Result Narrative

(NOTE)

Surgical Pathology Report

Patient Name:

Accession #:

Med. Rec #:

Submitting Physician:

ICD-O-3

Melanoma, spindle cell NOS
Site @ Choroid C69.3
8772/3
3/12/14

--- Clinical History ---

Malignant neoplasm of choroid [190.6]. Medical History: Thyroid disease.
Hypothyroidism. OSA (obstructive sleep apnea).

ADDENDA:

Addendum added:

---Final Pathologic Diagnosis---

A. Right eye, enucleation:

- Malignant melanoma, predominantly spindle cell type.

All controls show appropriate reactivity.

The immunohistochemical and/or in situ hybridization tests reported here, except for those addressing HER-2/neu overexpression, have been developed and their performance characteristics determined by the

at the and are not required to have nor do they have FDA approval.

Electronically Signed By

MD

[page 2 of 3]
---Addendum Report---

Addendum

Status: Signed Out

Unchanged.

The optic nerve margin is negative for tumor.

---Synoptic Report---

SYNOPTIC REPORT FOR UVEAL MELANOMA

Procedure:

Enucleation

Specimen Size:

2.2 X 2.2 X 2.2 cm

Anteroposterior diameter: 22 mm

Horizontal diameter: 22 mm

Vertical diameter: 22 mm

Length of optic nerve: 1.5 mm

Diameter of optic nerve: 1.5 mm

Specimen Laterality:

Right

Tumor Site:

Posterior central

Tumor Size:

1.9 x 1.9 x 1.0 cm

Tumor Involvement of Other Ocular Structures (select all that apply)

Sclera: tumor attached with focal invasion

Optic disc: involved

Vitreous: not involved

Choroid: involved

Ciliary body: not involved

Iris: not involved

Lens: not involved

Anterior chamber: not involved

Extrascleral extension (anterior): absent

Extrascleral extension (posterior): absent

Optic nerve: not involved

Retina: not involved

Histologic Type (E):

Spindle cell type

Margins:

Extrascleral extension (for enucleation specimens): absent

TNM Definitions.

TX primary tumor can not be ascertained

T0 no evidence of primary tumor

Iris:

T1 tumor limited to iris

T2 tumor confluent with or extending into the ciliary body and/or choroid

T3 As T2, with scleral extension

[page 3 of 3]
T4 tumor with extraocular extension

Ciliary body and choroid:

T1 tumor 12mm or less in diameter and 6mm or less in height

T2 tumor greater than 12mm but no more than 18mm in diameter and between 6 and 9mm in height

T3 tumor no more than 18mm in diameter and between 9 and 15mm in height

T4 tumor greater than 18mm in diameter and greater than 15mm in height

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists Protocols and the AJCC Cancer Staging Manual, 7th edition, 2010, for the reporting of cancer specimens.

---MICROSCOPIC:---

Histologic sections show a cellular neoplasm composed of plump, spindled cells arranged in fascicles involving the choroid with focal invasion into the sclera. The optic nerve, extra-scleral tissues, ciliary body, and lens are uninvolved. Occasional areas of pigment deposition are present in the tumor. Mitotic figures are frequent and necrosis is absent.

---SPECIMEN(S) RECEIVED:---

Neuropath, Eye, enucleation/evisceration

---GROSS DESCRIPTION:---

The specimen is received in one properly labeled container with the patient's name and accession number.

A. The specimen is designated "right eye" and consists of an intact globe measuring 2.2 cm from anterior to posterior, 2.4 cm from superior to inferior, and 2.4 cm from medial to lateral. The specimen is received previously incised from superior to inferior, in a coronal plane. The cornea measures 1.3 x 1.3 cm, is clear, and has a 0.6 cm dilated pupil. The optic nerve stump measures 0.3 x 0.2 cm. On cut section, there is a 1.9 (diameter) x 1.0 (height) cm dark brown mass, primarily located in the central eye slab. The lens is in situ. No detachment of the retina is noted.

RS 2

Summary of Cassettes: A1, central eye slab, horizontal section, anterior part; A2, central eye slab, horizontal section, posterior part; AX1, optic nerve

Note: Optic nerve margin to be submitted pending retrieval from Tissue Procurement.

Lab Use Only: Job ID

Gross description by:

Source: NCI Genomic Data Commons file d935b0e5-6d52-4691-a858-c081bcccff26 (TCGA-YZ-A985.61572A15-D011-4E41-A539-1FDB521F64F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).